Somatic mutation profile of tumor specimen HCM-CSHL-0059-C25-01A (aliquot HCM-CSHL-0059-C25-01A-11D-A77E-36) from HCMI case HCM-CSHL-0059-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 80.1 years (29,271 days).
Specimen HCM-CSHL-0059-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 968bc676-bba9-4566-b94b-c1e759e223a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0059-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0059-C25-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b2b133b-1cc5-4f20-8840-9059f4b2daa2

The open-access MAF lists 61 somatic variants for this specimen: 35 protein-altering or splice-affecting, 15 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 15, Intron 4, Nonsense Mutation 3, 5'UTR 2, 5'Flank 2, 3'UTR 1, Splice Site 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 30/286 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2
- ABHD8 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | catalogued as COSV99395437; called by muse, mutect2, varscan2
- ADAMTS13 | c.2953G>C p.D985H | Missense Mutation (SNP) | VAF 31/268 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV63021271; called by muse, mutect2, varscan2
- ADAMTS9 | c.4231C>T p.R1411W | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.93); catalogued as rs777954371; called by muse, mutect2, varscan2
- ATP13A2 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 23/332 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as rs773087322, COSV58701472, COSV58703639; ClinVar: uncertain significance; called by muse, mutect2
- CLEC18A | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 5/402 reads (1%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs764034494; called by muse, mutect2
- DCHS1 | c.9224G>A p.G3075D | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.549); catalogued as rs1227831355; called by muse, mutect2
- GRIA1 | c.2512C>T p.R838W | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs1454390322, COSV99599047; called by muse, mutect2, varscan2
- KCNJ16 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751812511, COSV52257673; called by muse, mutect2, varscan2
- KCNMA1 | c.2296C>T p.P766S (on ENST00000286628 / NM_001161352.2; = p.P708S on NM_002247.4) | Missense Mutation (SNP) | VAF 22/531 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs1299870502; called by muse, mutect2
- KRTAP4-16 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 40/418 reads (10%) | SIFT tolerated (0.18); catalogued as rs773219722; called by muse, mutect2, varscan2
- MAG | c.1429C>T p.R477W | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs780660604; called by muse, mutect2, varscan2
- MRGPRD | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs369321530, COSV58423252; called by muse, mutect2, varscan2
- MSN | c.1246C>A p.Q416K | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as COSV64304428; called by muse, varscan2
- MYH13 | c.4810G>A p.V1604M | Missense Mutation (SNP) | VAF 45/443 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs748902789, COSV52842383; called by muse, mutect2, varscan2
- OR2M2 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 32/325 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV62898654; called by muse, mutect2, varscan2
- PNPLA1 | c.1565C>T p.S522L (on ENST00000394571 / NM_001374623.1; = p.S427L on NM_173676.2) | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs747213173, COSV57235238; called by muse, mutect2
- RNH1 | c.877G>A p.G293S | Missense Mutation (SNP) | VAF 60/572 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs1346610742; called by muse, mutect2, varscan2
- TOPAZ1 | c.128G>A p.C43Y | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.009); catalogued as rs1459664054, COSV59067916; called by muse, mutect2, varscan2
- ARMC12 | c.617A>G p.Q206R (on ENST00000373866 / NM_001286574.2; = p.Q233R on NM_145028.5) | Missense Mutation (SNP) | VAF 8/191 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.34); called by muse, mutect2
- CCER1 | c.833A>T p.E278V | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- FGF13 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 40/413 reads (10%) | called by muse, mutect2
- IGF2R | c.6667G>T p.D2223Y | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IQSEC2 | c.3335C>T p.A1112V (on ENST00000642864 / NM_001111125.3; = p.A907V on NM_015075.2) | Missense Mutation (SNP) | VAF 69/421 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR5T3 | c.815T>A p.M272K | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.281); called by muse, mutect2
- RGPD4 | c.2927C>T p.A976V | Missense Mutation (SNP) | VAF 70/612 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- SETD6 | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- SF1 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 44/484 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); called by muse, mutect2
- SUPT20H | c.419G>C p.C140S (on ENST00000350612 / NM_001014286.3; = p.C141S on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE1 | c.471C>A p.S157R (on ENST00000367255 / NM_182961.4; = p.S164R on NM_033071.3) | Missense Mutation (SNP) | VAF 50/333 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- TSHZ3 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2
- UHRF1BP1L | c.1408-13_1414del p.X470_splice | Splice Site (DEL) | VAF 10/118 reads (8%) | called by mutect2, pindel
- WDR41 | c.1261A>T p.T421S | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.061); called by muse, mutect2
- ZNF100 | c.569C>G p.S190* | Nonsense Mutation (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2, varscan2
- ZNF429 | c.1037G>A p.C346Y | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- AC131160.1 | c.735C>T p.F245= | Silent (SNP) | VAF 74/426 reads (17%) | called by muse, mutect2, varscan2
- C20orf96 | c.459C>T p.T153= (on ENST00000360321 / NM_153269.3; = p.T152= on NM_080571.1) | Silent (SNP) | VAF 22/155 reads (14%) | called by muse, mutect2
- CABP2 | c.132C>T p.G44= | Silent (SNP) | VAF 29/261 reads (11%) | called by muse, mutect2, varscan2
- CALCRL | c.1305C>T p.D435= | Silent (SNP) | VAF 22/217 reads (10%) | called by muse, mutect2
- CSMD2 | c.3222C>T p.T1074= | Silent (SNP) | VAF 41/267 reads (15%) | catalogued as rs760608600, COSV53880145, COSV99593430; called by muse, mutect2, varscan2
- DOCK2 | c.5106A>T p.T1702= | Silent (SNP) | VAF 28/336 reads (8%) | called by muse, mutect2
- FAT2 | c.6918C>T p.D2306= | Silent (SNP) | VAF 29/188 reads (15%) | catalogued as rs756953964; called by muse, mutect2, varscan2
- GFRA3 | c.708C>T p.A236= | Silent (SNP) | VAF 27/223 reads (12%) | catalogued as rs1321252020; called by muse, mutect2, varscan2
- GRIN2B | c.3681G>A p.T1227= | Silent (SNP) | VAF 25/231 reads (11%) | catalogued as rs758736358, COSV101663255; called by muse, mutect2, varscan2
- MCM4 | c.1917T>G p.T639= | Silent (SNP) | VAF 45/203 reads (22%) | called by muse, mutect2, varscan2
- MMP2 | c.1764C>T p.F588= | Silent (SNP) | VAF 53/403 reads (13%) | called by muse, mutect2, varscan2
- N4BP2L2 | c.1047C>G p.P349= | Silent (SNP) | VAF 22/255 reads (9%) | called by muse, mutect2
- SGO2 | c.2328C>T p.N776= | Silent (SNP) | VAF 17/104 reads (16%) | called by muse, mutect2, varscan2
- SORCS3 | c.219G>A p.A73= | Silent (SNP) | VAF 52/311 reads (17%) | called by muse, varscan2
- WNT5A | c.927C>T p.C309= | Silent (SNP) | VAF 14/281 reads (5%) | catalogued as COSV52836178, COSV52838417; called by muse, mutect2
- ADGRE4P | n.1801C>T | RNA (SNP) | VAF 23/140 reads (16%) | catalogued as rs761337325; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827501 G>A | 3'Flank (SNP) | VAF 62/438 reads (14%) | catalogued as rs1459556905; called by muse, mutect2, varscan2
- AL359922.1 | c.348-35294_348-35277del | Intron (DEL) | VAF 50/528 reads (9%) | called by mutect2, pindel
- CHRND | c.*1215G>A | 3'UTR (SNP) | VAF 8/74 reads (11%) | catalogued as rs754249979; called by muse, mutect2, varscan2
- DUOX2 | c.1235-13C>A | Intron (SNP) | VAF 50/432 reads (12%) | called by muse, mutect2, varscan2
- LGALS13 | c.-18G>A | 5'UTR (SNP) | VAF 42/408 reads (10%) | catalogued as rs753900923, COSV99695047; called by muse, mutect2, varscan2
- RIMS2 | c.2196+18T>A | Intron (SNP) | VAF 14/78 reads (18%) | called by muse, varscan2
- RN7SL214P | chr15:77919068 C>T | 5'Flank (SNP) | VAF 82/628 reads (13%) | catalogued as rs751365138; called by muse, mutect2, varscan2
- VMA21 | chrX:151396944 G>A | 5'Flank (SNP) | VAF 40/345 reads (12%) | called by muse, mutect2, varscan2
- ZFP36L1 | c.-107C>T | 5'UTR (SNP) | VAF 18/139 reads (13%) | called by muse, mutect2, varscan2
- ZNF497 | c.-111-949C>T | Intron (SNP) | VAF 9/95 reads (9%) | catalogued as rs903305617, COSV100217983; called by muse, mutect2
